Somatic mutation profile of tumor specimen TCGA-AD-6548-01A (aliquot TCGA-AD-6548-01A-11D-1835-10) from TCGA case TCGA-AD-6548, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Splenic flexure of colon; AJCC pathologic stage: Stage I; Age at diagnosis: 81.5 years (29,758 days).
Specimen TCGA-AD-6548-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa12864d-8e87-42b3-8281-3615f49bff2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-6548-10A (Blood Derived Normal), aliquot TCGA-AD-6548-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1abce30f-9954-4564-ae77-e937e9b7a6f5

The open-access MAF lists 136 somatic variants for this specimen: 95 protein-altering or splice-affecting, 40 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 40, Nonsense Mutation 8, Frame Shift Del 5, In Frame Ins 1, 3'UTR 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3871C>T p.Q1291* | Nonsense Mutation (SNP) | VAF 34/66 reads (52%) | catalogued as rs1561588104, CM021065, CM053765, COSV57321476, COSV57325789, COSV57375930; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 25/112 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.647T>G p.V216G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520004, COSV52676908, COSV52856938, COSV52866969, COSV53036902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7297T>A p.S2433T | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV71289920; called by muse, mutect2, varscan2
- ABLIM1 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs760288341, COSV53301734, COSV53316744; called by muse, mutect2, varscan2
- ADA2 | c.1040A>T p.D347V (on ENST00000262607; = p.D106V on NM_177405.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV99376003; called by muse, mutect2, varscan2
- ATP10A | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.115); catalogued as COSV63518915; called by muse, mutect2
- ATP6V1B1 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52270046; called by muse, mutect2, varscan2
- ATRNL1 | c.3828C>A p.S1276R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100370577; called by muse, mutect2
- BHMT2 | c.1031A>G p.E344G | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99670072; called by muse, mutect2
- BICRA | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.565); catalogued as COSV101194317; called by muse, mutect2, varscan2
- BICRA | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV67605134; called by muse, mutect2, varscan2
- CDH18 | c.1777A>G p.R593G | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as COSV99934591; called by muse, mutect2, varscan2
- CECR2 | c.1100C>G p.A367G (on ENST00000342247 / NM_001290047.2; = p.A204G on NM_001290046.1) | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99377872; called by muse, mutect2, varscan2
- CFHR1 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.11); catalogued as COSV57627610; called by muse, mutect2, varscan2
- CLDN22 | c.245T>G p.I82S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100032873; called by muse, mutect2, varscan2
- COL19A1 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59576312, COSV59586540; called by muse, mutect2, varscan2
- COL23A1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.45); PolyPhen benign (0.258); catalogued as rs563255101, COSV66792110; called by muse, mutect2, varscan2
- COL5A1 | c.1942C>G p.P648A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.956); catalogued as COSV100879898; called by muse, mutect2, varscan2
- CTSG | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1410506597, COSV53535308; called by muse, varscan2
- CYLC1 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.243); catalogued as COSV61412952; called by muse, mutect2
- DCN | c.425A>C p.K142T | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99272159; called by muse, mutect2
- DDX23 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs759085933, COSV57283865; called by muse, mutect2, varscan2
- DIAPH2 | c.1187A>G p.N396S | Missense Mutation (SNP) | VAF 64/367 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as rs1209311891, COSV61274137; called by muse, mutect2, varscan2
- DLX5 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56032369; called by muse, mutect2, varscan2
- DNAH5 | c.5441C>T p.T1814I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV99449499; called by muse, mutect2
- ELMO1 | c.1846G>A p.V616M | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs762928031, COSV100166182, COSV60302454; called by muse, mutect2, varscan2
- EMILIN1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs763085035, COSV66694949; called by muse, mutect2, varscan2
- EPHB1 | c.1495G>A p.G499S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV101213151, COSV67658770; called by muse, mutect2
- FAT3 | c.3467T>C p.V1156A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV53125802; called by muse, mutect2, varscan2
- FAT4 | c.6425T>G p.V2142G | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58709392; called by muse, mutect2, varscan2
- FBLN7 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs369700908; called by muse, mutect2, varscan2
- FBXO41 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745628191, COSV54585871; called by muse, mutect2, varscan2
- FBXW7 | c.1111A>T p.K371* (on ENST00000281708 / NM_001349798.2; = p.K291* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 30/147 reads (20%) | catalogued as COSV55964456; called by muse, mutect2, varscan2
- FCSK | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99850842; called by muse, mutect2, varscan2
- FURIN | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763052854, COSV99184675; called by muse, mutect2
- GLT8D2 | c.405G>T p.L135= | Splice Region (SNP) | VAF 6/34 reads (18%) | catalogued as rs1293910917, COSV100674041; called by muse, mutect2
- GOLGA3 | c.3365C>T p.T1122M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.927); catalogued as rs753775630, COSV99204400; called by muse, mutect2, varscan2
- GRM7 | c.944G>T p.S315I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV100736452; called by muse, mutect2, varscan2
- HAP1 | c.1022_1023del p.L341Rfs*3 | Frame Shift Del (DEL) | VAF 41/89 reads (46%) | catalogued as COSV57878819; called by mutect2, pindel
- HCCS | c.77C>G p.P26R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100335624, COSV100335674; called by muse, mutect2
- HPS3 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs752988768, COSV56055188; called by muse, mutect2, varscan2
- IFNA14 | c.58T>G p.C20G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.901); catalogued as COSV66516207; called by muse, mutect2
- IGFN1 | c.1404G>T p.Q468H (on ENST00000295591 / NM_001367841.1; = p.Q2925H on NM_001164586.2) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55179184, COSV99812189; called by muse, mutect2
- IGSF9 | c.1370G>A p.R457Q (on ENST00000368094 / NM_001135050.2; = p.R441Q on NM_020789.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.876); catalogued as rs200623535; called by muse, mutect2, varscan2
- IGSF9B | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.111); catalogued as COSV58069041; called by muse, mutect2
- IQUB | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs140581147; called by muse, mutect2, varscan2
- KCNK15 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100865125; called by muse, mutect2, varscan2
- KHDRBS1 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.127); catalogued as COSV56982417; called by muse, mutect2, varscan2
- LMLN | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs180983819, COSV57601966; called by muse, mutect2, varscan2
- LRIT1 | c.1200C>A p.S400R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV64512925; called by muse, mutect2, varscan2
- LYZL1 | c.304G>A p.G102S (on ENST00000375500; = p.G56S on NM_032517.6) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.551); catalogued as rs564091905, COSV64966575; called by muse, mutect2, varscan2
- MAP2K4 | c.656T>C p.L219S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62258202; called by muse, mutect2
- MARCHF11 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as COSV100197906; called by muse, mutect2, varscan2
- MUL1 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV51642099; called by muse, mutect2, varscan2
- NLRP6 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs774708807, COSV56458892; called by muse, mutect2, varscan2
- NOXRED1 | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53628263; called by muse, mutect2, varscan2
- NRXN1 | c.1868C>A p.A623D | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.267); catalogued as COSV100454994; called by muse, mutect2
- OPRPN | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as rs748377067, COSV68192942; called by muse, mutect2, varscan2
- OR10K1 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs766692849, COSV56871553; called by muse, mutect2, varscan2
- OR2A2 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as rs766513919, COSV68871787; called by muse, mutect2, varscan2
- OR5D14 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV59456819; called by muse, mutect2, varscan2
- OTOGL | c.6614C>T p.A2205V (on ENST00000547103; = p.A2196V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs574033095, COSV54013021; called by muse, mutect2, varscan2
- P2RY10 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.463); catalogued as rs1232399249, COSV99409122; called by muse, mutect2, varscan2
- PAPPA2 | c.3631A>T p.T1211S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV100868073; called by muse, mutect2, varscan2
- PAX3 | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60588280; called by muse, mutect2
- PCDH17 | c.2678G>T p.G893V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV100931625, COSV64979381; called by muse, mutect2, varscan2
- PDCD6 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.852); catalogued as rs1378816110, COSV99372753; called by muse, mutect2, varscan2
- PDZD3 | c.770G>A p.R257Q (on ENST00000531114; = p.R191Q on NM_024791.4) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs1172904668, COSV52705790; called by muse, mutect2, varscan2
- PIWIL1 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199654827; called by muse, mutect2, varscan2
- RNF128 | c.1273G>T p.E425* (on ENST00000255499 / NM_194463.2; = p.E399* on NM_024539.3) | Nonsense Mutation (SNP) | VAF 30/159 reads (19%) | catalogued as COSV55251939; called by muse, mutect2, varscan2
- S1PR4 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs766414904, COSV55740349; called by muse, mutect2, varscan2
- SETD2 | c.7355C>T p.S2452L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775780402, COSV57434569; called by muse, mutect2, varscan2
- SOBP | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs1386634457, COSV100433106, COSV58001308; called by muse, mutect2, varscan2
- SOX9 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as CM114590, COSV55427556; called by muse, mutect2, varscan2
- SPART | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs747665041, COSV100768724; called by mutect2, varscan2
- SUSD6 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV61365702; called by muse, mutect2, varscan2
- TAF1L | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV54263541; called by muse, varscan2
- TCF7 | c.484_487del p.L162Tfs*36 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs760546259; called by mutect2, pindel, varscan2
- TGM4 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145801637, COSV56094491; called by muse, mutect2
- THOC3 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1403781143, COSV99442105; called by muse, mutect2, varscan2
- TRMT10C | c.393del p.K131Nfs*3 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs760928888; called by mutect2, varscan2
- TRO | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV51502897; called by muse, mutect2, varscan2
- TSC1 | c.3428C>T p.P1143L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.115); catalogued as rs201867031, COSV53763286; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTN | c.22735G>A p.E7579K (on ENST00000591111; = p.E6652K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | PolyPhen possibly damaging (0.749); catalogued as rs786205400, COSV60131729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VAX2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782124147, COSV52266164; called by muse, mutect2, varscan2
- WDR90 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1378701335, COSV53471209; called by muse, varscan2
- ZNF208 | c.939C>A p.Y313* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV68107940; called by muse, mutect2, varscan2
- ZNF227 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100480370; called by muse, varscan2
- ZNF536 | c.3434T>A p.V1145D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.006); catalogued as COSV100835202; called by muse, mutect2, varscan2
- COL6A6 | c.239_241dup p.H80dup | In Frame Ins (INS) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- DOCK9 | c.4115_4116del p.L1372Hfs*3 (on ENST00000376460 / NM_001366676.2; = p.L1373Hfs*3 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by pindel, varscan2
- HNRNPC | c.440dup p.P148Sfs*29 (on ENST00000420743; = p.P135Sfs*29 on NM_004500.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 14/69 reads (20%) | called by mutect2, pindel, varscan2
- PLCH1 | c.3095_3099del p.L1032Pfs*29 (on ENST00000340059 / NM_001130960.2; = p.L1024Pfs*29 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by pindel, varscan2
- TUBGCP6 | c.3100C>T p.L1034F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AGTPBP1 | c.2844A>G p.R948= (on ENST00000357081 / NM_001330701.2; = p.R908= on NM_015239.2) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100429728; called by muse, mutect2, varscan2
- CACNA1S | c.4374C>T p.D1458= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs757017761, COSV62940659; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAPN12 | c.1251G>A p.R417= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs758064549, COSV61016735; called by muse, mutect2, varscan2
- CDH22 | c.510C>T p.H170= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs368622255; called by muse, mutect2, varscan2
- CES1 | c.348T>C p.C116= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs768571626, COSV100828669; called by mutect2, varscan2
- COL16A1 | c.4254G>A p.S1418= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs374803719; called by muse, mutect2, varscan2
- CPXCR1 | c.153G>A p.R51= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV52162795; called by muse, mutect2, varscan2
- CYP46A1 | c.1272G>A p.R424= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99952610; called by muse, mutect2, varscan2
- CYP51A1 | c.621C>G p.L207= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV50152235; called by muse, mutect2, varscan2
- DNAH17 | c.849C>T p.N283= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs541514193, COSV67755032; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.123C>A p.T41= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV55744473; called by muse, mutect2, varscan2
- FADS6 | c.897G>A p.S299= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1270541200, COSV59601342; called by muse, mutect2, varscan2
- FKBP14 | c.624C>T p.H208= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs757161961, COSV56107433; called by muse, mutect2, varscan2
- HLA-DPB1 | c.12G>T p.L4= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV69603389; called by muse, mutect2, varscan2
- HPS5 | c.75C>G p.L25= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs755901755, COSV99786448; called by muse, mutect2, varscan2
- HSD3B1 | c.180A>G p.E60= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99347929; called by muse, mutect2, varscan2
- KDM4A | c.3087T>A p.I1029= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV53512692, COSV53515273; called by muse, mutect2, varscan2
- KDM7A | c.2805C>T p.G935= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as rs746262114, COSV50092571; called by muse, mutect2, varscan2
- KIRREL3 | c.222C>T p.Y74= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs745333764, COSV73105087; ClinVar: likely benign; called by mutect2, varscan2
- LONRF3 | c.600C>T p.S200= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV59153379; called by muse, mutect2, varscan2
- LRP2 | c.7902C>T p.L2634= | Silent (SNP) | VAF 42/132 reads (32%) | catalogued as COSV99788330; called by muse, mutect2, varscan2
- MAML2 | c.1953G>A p.Q651= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs539210719, COSV101594081; called by muse, mutect2, varscan2
- MCF2 | c.495G>T p.V165= | Silent (SNP) | VAF 74/209 reads (35%) | catalogued as COSV100644757; called by muse, mutect2, varscan2
- MUC16 | c.4212A>G p.K1404= | Silent (SNP) | VAF 51/229 reads (22%) | catalogued as rs753275982, COSV67473614; called by muse, mutect2, varscan2
- PCDHGA12 | c.1884G>A p.T628= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV52742428, COSV52755079; called by muse, mutect2, varscan2
- PLD4 | c.396C>T p.S132= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs776782761, COSV101190492; called by muse, mutect2, varscan2
- PNMA3 | c.183C>T p.N61= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1030475150, COSV64722497; called by muse, mutect2, varscan2
- PPFIA2 | c.2598C>A p.G866= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100333300; called by muse, mutect2, varscan2
- PRICKLE2 | c.2253C>T p.S751= (on ENST00000295902; = p.S695= on NM_198859.4) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1174848549, COSV55767416; called by muse, mutect2
- SDCBP | c.378A>T p.G126= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV52706121; called by muse, mutect2, varscan2
- SEMA3A | c.1821T>C p.Y607= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99546526; called by muse, mutect2, varscan2
- SH3TC1 | c.873C>T p.D291= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs151285463; called by muse, mutect2, varscan2
- TGFB2 | c.81C>T p.L27= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV65109684; called by muse, mutect2, varscan2
- TMEM198 | c.345C>T p.S115= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs200927556, COSV54721852; called by muse, mutect2
- TPMT | c.105C>T p.N35= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs367678410, COSV59429183; called by muse, mutect2, varscan2
- TRPV5 | c.375T>G p.V125= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99520506; called by muse, mutect2, varscan2
- UACA | c.573G>A p.A191= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs759163989, COSV59856640; called by muse, mutect2, varscan2
- UBTD1 | c.183C>T p.F61= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs763391490, COSV53968546; called by muse, mutect2, varscan2
- UNC79 | c.4614C>T p.I1538= (on ENST00000393151 / NM_001346218.2; = p.I1361= on NM_020818.5) | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1391980240, COSV56381742, COSV99830257; called by muse, mutect2, varscan2
- ZBTB10 | c.1203T>G p.P401= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as COSV66947849; called by muse, mutect2
- SOHLH1 | c.*547G>T | 3'UTR (SNP) | VAF 6/35 reads (17%) | catalogued as COSV53682528; called by muse, mutect2
